Gene-level copy-number profile of tumor specimen TCGA-66-2758-01A from TCGA case TCGA-66-2758, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 71.8 years (26,209 days).
Specimen TCGA-66-2758-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.3ed721c2-9d7b-4547-be8f-e9506ccb5dc6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-66-2758-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a2f53e28-594f-4f9f-90a7-622c987c9809

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 42; copy number 1: 1,910; copy number 2: 25,354; copy number 3: 12,970; copy number 4: 12,554; copy number 5: 4,939; copy number 6: 813; copy number 7: 812; copy number 8: 291; copy number 9: 120; copy number 11: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-66-2758-01A-02D-1969-01): tumor purity 0.5, ploidy 2.96, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 42 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,929,457–26,805,862, 39 genes: ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1.
- chr10:19,816,239–20,289,856, 3 genes (within-gene range 0–2): PLXDC2, AC069549.1, AC069549.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,982 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–155,934,413, 579 genes, copy number 5 (broad region; genes not listed).
- chr1:159,649,151–162,979,793, 146 genes, copy number 5 (broad region; genes not listed).
- chr1:173,714,941–235,883,640, 1,211 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr3:56,557,161–58,537,283, 47 genes, copy number 5: CCDC66, TASOR, ARHGEF3, ARHGEF3-AS1, SPATA12, AC097358.2, IL17RD, AC097358.1, HESX1, APPL1, ASB14, AC093928.1, DNAH12, Y_RNA, RNU6-1181P, RNF7P1, AC092418.1, RNU6-108P, RNU6-483P, AC092418.2, PDE12, ARF4, ARF4-AS1, RNU6ATAC26P, DENND6A, DENND6A-AS1, DENND6A-DT, SLMAP, PDHA1P1, PPIAP16, FLNB, FLNB-AS1, AC137936.1, AC137936.2, DNASE1L3, ABHD6, HTD2, RPP14, AC098479.1, PXK, AC135507.2, PDHB, AC135507.1, AC116036.2, KCTD6, ACOX2, AC116036.1.
- chr3:58,572,744–58,574,319, 1 gene, copy number 5: AC119424.1.
- chr3:118,900,557–120,513,188, 48 genes, copy number 7: IGSF11, IGSF11-AS1, TEX55, AC083800.1, UPK1B, B4GALT4, B4GALT4-AS1, ARHGAP31, RPS26P21, ARHGAP31-AS1, RNU6-1127P, TMEM39A, POGLUT1, AC073352.1, TIMMDC1, CD80, AC073352.2, ADPRH, PLA1A, RPL10P7, POPDC2, COX17, AC023494.1, CFAP91, AC069444.2, AC069444.1, NR1I2, PHBP8, GSK3B, AC092910.4, AC078856.1, AC092910.1, AC092910.2, AC092910.3, RN7SL762P, RN7SL397P, GPR156, Y_RNA, AC063952.2, LRRC58, AC063952.1, AC063952.4, AC063952.3, FSTL1, MIR198, AC126182.3, AC126182.1, AC126182.2.
- chr3:140,941,830–141,471,902, 12 genes, copy number 6: SLC25A36, AC108727.1, SPSB4, AC108727.2, PXYLP1, AC022215.2, AC022215.1, AC117383.1, AC117383.2, ZBTB38, AC010184.1, KRT18P35.
- chr3:148,985,868–165,846,519, 261 genes, copy number 7 (broad region; genes not listed).
- chr3:171,504,245–198,222,513, 533 genes, copy number 6–8 (broad region; genes not listed).
- chr5:58,198–45,895,970, 709 genes, copy number 5–9 (broad region; genes not listed).
- chr7:99,876,958–140,924,929, 752 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:96,126,967–145,066,685, 778 genes, copy number 5 (broad region; genes not listed).
- chr9:14,475–10,612,723, 148 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr10:44,712–689,668, 13 genes, copy number 5 (within-gene range 2–5): AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26.
- chr12:66,767–5,946,232, 138 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr12:16,347,142–16,609,259, 1 gene, copy number 6 (within-gene range 4–6): MGST1.
- chr12:16,513,445–22,065,674, 74 genes, copy number 6 (broad region; genes not listed).
- chr12:22,104,491–22,134,851, 2 genes, copy number 6: AC007671.1, SULT6B2P.
- chr15:72,199,029–88,546,585, 465 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr15:91,853,708–96,300,990, 70 genes, copy number 5–11 (within-gene range 3–11) (broad region; genes not listed).
- chr15:96,112,628–96,140,452, 2 genes, copy number 11: AC012409.5, AC012409.3.
- chr16:74,842,587–83,800,640, 173 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr18:47,390–15,330,282, 376 genes, copy number 5–7 (broad region; genes not listed).
- chr20:87,250–1,940,592, 61 genes, copy number 5 (broad region; genes not listed).
- chr20:31,404,845–33,111,751, 67 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr22:40,044,817–50,801,309, 315 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,521. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
